Somatic mutation profile of tumor specimen TARGET-10-PARRVI-09A (aliquot TARGET-10-PARRVI-09A-01D) from TARGET case TARGET-10-PARRVI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,889 days).
Specimen TARGET-10-PARRVI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b841cc8e-2c0b-47d6-adab-0c02dfc7e3ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRVI-10A (Blood Derived Normal), aliquot TARGET-10-PARRVI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b85b31b-d3a4-4edd-9928-b945c204c85f

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.3695T>C p.L1232P | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM158321; called by muse, mutect2, varscan2
- FAM47C | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1262834503, COSV100792252, COSV63728751; called by muse, mutect2, varscan2
- HNRNPU | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.074); catalogued as COSV51694862; called by muse, mutect2
- MUC17 | c.5597G>A p.S1866N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs200081448, COSV60279546, COSV60286919; called by muse, mutect2, varscan2
- PAN2 | c.3151G>T p.D1051Y (on ENST00000425394 / NM_001127460.3; = p.D1047Y on NM_014871.5) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228264; called by muse, mutect2
- PDZRN3 | c.2969G>A p.R990Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1235466420, COSV99727885; called by muse, mutect2, varscan2
- SALL3 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs142929767, COSV73305804; called by muse, mutect2, varscan2
- TMEM171 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs755696036, COSV55131622; called by mutect2, varscan2
- TNFAIP2 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs1348601213; called by muse, mutect2, varscan2
- TTC28 | c.3389G>C p.S1130T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1187060057; called by muse, varscan2
- ZMIZ1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV57899767; called by muse, mutect2, varscan2
- AMZ2 | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- ANXA4 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CARD6 | c.2136C>A p.S712R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, varscan2
- DACH1 | c.1058G>C p.S353T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EVA1B | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- KLHL36 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYOT | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- NLRP1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- PCDHA6 | c.638C>A p.T213K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.399); called by muse, mutect2
- SIM1 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SUV39H1 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- USP24 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ATP1B4 | c.996G>A p.K332= (on ENST00000218008 / NM_001142447.3; = p.K328= on NM_012069.5) | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs1056958645; called by muse, mutect2, varscan2
- GBA3 | c.738C>T p.A246= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs943614618; called by muse, mutect2, varscan2
- GLIS3 | c.1254T>A p.G418= | Silent (SNP) | VAF 73/139 reads (53%) | called by muse, mutect2, varscan2
- GOPC | c.888T>C p.H296= | Silent (SNP) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- HSP90AB1 | c.1911G>A p.T637= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as rs1411250095, COSV99241270; called by muse, mutect2, varscan2
- SYT16 | c.1851T>C p.S617= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1264C>T | RNA (SNP) | VAF 19/94 reads (20%) | catalogued as rs769683519; called by muse, mutect2, varscan2
- PNP | c.461+13C>T | Intron (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1032-44C>A | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
